Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6474, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6474-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY REPORT

Accession number:

Final Report

DIAGNOSIS:

- 1-3) SOFT TISSUE, LEFT NECK, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 4) SOFT TISSUE, LEFT NECK LEVEL 1, EXCISION: 7 BENIGN LYMPH NODES; BENIGN SALIVARY GLAND TISSUE.
- 5) SOFT TISSUE, LEFT NECK LEVEL 2, EXCISION: MULTIPLE MATTED LYMPH NODES INVOLVED BY METASTATIC SQUAMOUS CELL CARCINOMA.
- 6) SOFT TISSUE, LEFT NECK LEVEL 3, EXCISION: MULTIPLE FRAGMENTS OF LYMPH NODES AND SUBCUTANEOUS TISSUE INVOLVED BY SQUAMOUS CELL CARCINOMA.
- 7) SOFT TISSUE, LEFT NECK LEVEL 4, EXCISION: 3 BENIGN LYMPH NODES.
- 8) SOFT TISSUE, LEFT NECK LEVEL 5, EXCISION: 8 BENIGN LYMPH NODES.
- 9) LARYNX, PHARYNX, AND THYROID, LEFT NECK AND RESECTION: MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 3.5 CM IN GREATEST DIMENSION, INVOLVING THE LEFT PYRIFORM SINUS WITH EXTENSION INTO THE FALSE VOCAL CORDS AND THE RIGHT ARYTENOID; THE TUMOR FOCALLY EXTENDS TO THE SUPERIOR INKED SPECIMEN EDGE; INVASION OF LYMPHATIC VESSELS AND NERVES IS PRESENT; NEGATIVE FOR FIXATION OF VOCAL CORDS; TWO OF THIRTEEN (2/13) LYMPH NODES INVOLVED BY SQUAMOUS CELL CARCINOMA; (SEE COMMENT).
- 10) SOFT TISSUE, RIGHT TONGUE, BIOPSY: INVOLVED BY SQUAMOUS CELL CARCINOMA.
- 11-14) SOFT TISSUE, RIGHT ORAL CAVITY, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 15) SOFT TISSUE, TONGUE BASE, BIOPSY: INVOLVED BY SQUAMOUS CELL CARCINOMA IN SITU WITH FOCAL SUPERFICIAL INVASION.
- 16) SOFT TISSUE, RIGHT TONGUE BASE, RESECTION: POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 2.5 CM IN GREATEST DIMENSION (SEE COMMENT).
- 17-19) SOFT TISSUE, ORAL CAVITY, BIOPSY: NEGATIVE FOR MALIGNANCY.

COMMENT: The tumor lesion in the pyriform sinus corresponds to AJCC stage IVA (pT2, N2b, MX). Assuming the tumor in the base of the tongue represents a separate lesion, it corresponds to AJCC stage II (pT2).

[page 2 of 8]
Although the lesion in specimen 9 is noted to extend to an inked edge, the final surgical margins of resection, represented separately, are negative for malignancy.

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: Dr. [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)anterior inferior skin margin left neck; 2)anterior superior skin margin left neck; 3)posterior left skin margin left neck; 4)left neck level 1; 5)left neck level 2; 6)left neck level 3 and skin; 7)left neck level 4; 8)left neck level 5; 9)larynx, pharynx, thyroid, level 6 nodes; 10)right tongue base biopsy; 11)stomal mucosal margin; 12)post cricoid mucosal margin; 13)right pharyngeal mucosal margin; 14)left pharyngeal mucosal margin; 15)tongue base mucosal margin; 16)right tongue base and pharyngeal wall, stitch anterior, small piece is posterior to main specimen; 17) anterior tongue base mucosal margin; 18)anterior oral tongue margin; 19) right pharyngeal wall mucosal margin #2

GROSS DESCRIPTION:

1) SOURCE: Anterior Inferior Left Neck Skin Margin

Received fresh labeled "anterior inferior skin margin, left neck" is a 3.1 x 0.1 x 0.1 cm thin strip of pink-tan skin with underlying pink subcutaneous tissue. The anterior edge is inked black and the tissue is submitted entirely for frozen section.

Summary of sections: 1AFSC, 1/1.

2) SOURCE: Anterior Superior Left Neck Skin Margin

Received fresh labeled "anterior superior skin margin left neck" is a 4.9 x 0.2 x 0.2 strip of pink-tan skin with underlying pink subcutaneous tissue. The anterior portion is inked black and the specimen is submitted entirely for frozen section.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Posterior Left Neck Skin Margin

[REDACTED]

[page 3 of 8]
Received fresh labeled "posterior skin margin left neck" is a 3.4 x 0.3 x 0.2 cm strip of pink-tan skin with underlying pink subcutaneous tissue. The inferior portion is inked black and the specimen is entirely submitted for frozen section.

Summary of sections: 3AFSC, 1/1.

4) SOURCE: Left Neck Level 1

Received fresh labeled "left neck level 1" is a 6.0 x 4.5 x 2.0 cm portion of yellow-tan lobular fibrofatty tissue. The specimen is dissected for lymph nodes, and upon sectioning there is a 3.5 x 2.2 x 2.0 cm tan-gold bosselated gland. Sectioning this portion of gland shows a lobular, trabecular cut surface. Representative sections submitted.

Summary of sections: 4A, five lymph nodes, 5/1; 4B, two lymph nodes, one bisected (larger lymph node bisected with smaller lymph node inked blue), 3/1; 4C, section of gland, 2/1.

5) SOURCE: Left Neck Level 2

Received fresh labeled "left neck level 2" is a 6.0 x 5.5 x 3.5 cm portion of yellow-tan lobular fibrofatty tissue admixed with red-brown skeletal muscle. Noted at one long axis end is a circumscribed nodule. This nodule is inked and sectioned to show a cluster of suspected lymph nodes, having a yellow-gray soft pasty cut surface. A portion of this tissue is submitted to [REDACTED] Representative sections are submitted.

Summary of sections: 5A-5C, suspected cluster of matted lymph nodes/skeletal muscle, 2/1 each; 5D, possible small lymph nodes, 8/1.

6) SOURCE: Left Neck Level 3 and Skin

Received fresh labeled "left neck level 3 with skin" is a 5.0 x 5.0 x 2.5 cm portion of yellow-tan tissue admixed with red-brown skeletal muscle. The specimen is partially covered by a dusky tan-purple skin ellipse measuring 2.9 x 1.9 cm. Serial sectioning shows a yellow-tan lobular fibrofatty cut surface with the subcutaneous tissue showing a stellate orange-yellow discoloration. Representative sections are submitted.

Summary of sections: 6A, four suspected lymph nodes, 4/1; 6B-6C, skin with subcutaneous tissue, 1/1 each.

7) SOURCE: Left Neck Level 4

Received fresh labeled "left neck level 4" is a 6.0 x 4.0 x 2.8 cm portion of yellow-tan lobular fibrofatty tissue admixed with red-brown skeletal muscle. The suspected lymph nodes are submitted.

Summary of sections: 7A, 4/1.

8) SOURCE: Left Neck Level 5

Received fresh labeled "left neck level 5" is a 7.0 x 5.5 x 2.5 cm portion of yellow-tan lobular fibrofatty tissue. The suspected lymph nodes are submitted.

Summary of sections: 8A, six lymph nodes, 6/1; 8B, four lymph nodes, 4/1.

9) SOURCE: Larynx, Pharynx, Thyroid, Level 6 Nodes

[page 4 of 8]
Received fresh labeled, "larynx, pharynx, thyroid, level 6 lymph nodes," is a 9.0 x 4.5 x 3.5 cm laryngeal specimen. The specimen is inked as follows: left-blue, right-black. After inking the specimen, the anterior larynx is opened to reveal all structures described. Within the specimen, there is a 5.5 x 3.4 x 2.5 cm left pharynx. The epiglottis measures 3.5 x 3.0 x 0.2 cm with a pink-tan mucosal surface. Distal to the epiglottis are the bilateral arytenoids, which measure 2.1 x 0.8 x 0.7 cm on the left and 1.5 x 0.9 x 0.5 cm on the right. Both arytenoids are pink-tan and soft with no gross abnormalities. The false vocal cords measure 2.0 cm on the left and 1.5 cm on the right. Distal to the false vocal cords are the bilateral ventricles and true vocal cords. The true vocal cords measure 1.8 cm on the left and 2.0 cm on the right. Bilateral false and true vocal cords are pink-tan in color. Distal to the true vocal cords is the subglottis, which leads to the trachea. There is a 2.6 cm portion of trachea removed with the specimen. The posterior surface of the specimen contains the hyoid bone, which is identified superiorly to the horns of the cricoid cartilage. The horn of the left cricoid cartilage is not grossly visible. The left piriform sinus contains a nodular pink-tan lesion that measures 3.5 x 3.0 cm. The lesion involves the entire piriform sinus. On the posterior side of the specimen, there is muscle tissue identified and a vein that measures 9.5 x 3.5 cm. The vein is clipped at both ends. The left lobe of the thyroid is identified and measures 3.5 x 2.6 x 0.8 cm. Also removed distal to the thyroid gland are the level 6 lymph nodes. The level 6 tissue is removed from the specimen and thoroughly examined for lymph nodes. There are multiple palpable lymph nodes. Approximately 12 possible lymph nodes are identified and entirely submitted. The largest presumed lymph node measures 2.0 x 0.8 x 0.8 cm. It is bisected to reveal a cystic cavity filled with thick white fluid. The thyroid is removed from the specimen and serially sectioned to reveal a red-brown, gritty parenchyma with a mucoid surface. There is a 0.1 cm firm, white nodule within the parenchyma approaching the isthmus. There is no gross evidence of tumor. Representative sections of the thyroid are submitted. The soft tissue on the posterior aspect of the specimen is removed. The identified vein prior to inking is removed and the remaining tissue is serially sectioned to reveal grossly normal muscle and cartilage tissue. While sectioning the specimen, a lymph node is identified that measures 2.0 x 1.1 x 0.2 cm. The remaining tissue on the possible posterior larynx is thoroughly examined and one additional presumed lymph node is identified. The remaining tissue is grossly normal. Both lymph nodes are entirely submitted. The piriform sinus is serially sectioned while attached to the remaining specimen. The tumor is less than 0.1 cm to the posterior margin, 0.1 cm from the superior margin, and 1.5 cm from the inferior margin. The lesion is 2.0 cm thick. Representative sections of the tumor and remaining specimen are submitted.

Summary of sections: 9A, tumor to posterior margin, 1/1; 9B, tumor to superior margin, 6/1; 9C-D, representative sections of tumor, 2/1 each; 9E, representative sections of thyroid, 2/1; 9F, representative sections of epiglottis, 2/1; 9G, left epiglottic fold, 2/1; 9H, right epiglottic fold, 2/1; 9I, right arytenoid, 1/1; 9J, left arytenoid nerve invasion, 1/1; 9K, left false vocal cord involving lymphatics, 1/1; 9L, right false vocal cord, 1/1; 9M, left true vocal cord, 1/1; 9N, right true vocal cord and representative section of posterior muscle, 2/1; 9O, posterior tracheal margin and representative sections of vein, 3/1; 9P, level 6 cystic mass, 2/1; 9Q-S, possible level 6 lymph nodes, m/1 each; 9T-U, posterior larynx

[page 5 of 8]
possible lymph nodes, 1/1 each.

10) SOURCE: Right Tongue Base Biopsy

Received fresh labeled "right tongue base biopsy" is a 1.5 x 0.8 x 0.3 cm segment of pink-tan soft tissue with a small segment of the tongue surface. The specimen is submitted entirely for frozen section.

Summary of sections: 10AFSC, 1/1.

11) SOURCE: Stomal Mucosa Margin

Received fresh labeled "stomal mucosal margin" is a 2.0 x 0.2 x 0.2 cm strip of pink-tan soft tissue. The specimen is received on a towel with orientation marked by the letter "R" at one end. The right side of the specimen is inked black and the specimen is submitted entirely for frozen section.

Summary of sections: 11AFSC, 1/1.

12) SOURCE: Post Cricoid Mucosal Margin

Received fresh labeled "post cricoid mucosal margin" on a towel is a strip of pink-tan tissue measuring 3.0 x 0.3 x 0.3 cm. The specimen is oriented with the letter "R" at one end. The right side of the specimen is inked black. The specimen is submitted entirely for frozen section.

Summary of sections: 12AFSC, 1/1.

13) SOURCE: Right Pharyngeal Mucosal Margin

Received fresh on a towel labeled "right pharyngeal mucosal margin" is a 6.0 x 0.2 x 0.2 cm strip of pink-tan mucosa. The specimen is oriented with the letter "S" at one end. The superior portion of the specimen is inked black. The specimen is submitted entirely for frozen section.

Summary of sections: 13AFSC, 1/1.

14) SOURCE: Left Pharyngeal Mucosal Margin

Received fresh on a towel labeled "left pharyngeal mucosal margin" is an 8.0 x 0.3 x 0.2 cm strip of pink-tan mucosa oriented by the letter "F" at one end. The superior segment of the tissue is inked black. The specimen is submitted entirely for frozen section and subsequently submitted for permanent section.

Summary of sections: 14AFSC, 1/1.

15) SOURCE: Tongue Base Mucosal Margin

Received fresh labeled "tongue base mucosal margin" is a strip of pink-tan mucosa measuring 5.0 x 0.3 x 0.4 cm. The specimen is oriented with the letter "R" written on the towel it is received on. The right side of the specimen is inked black. The specimen is submitted entirely for frozen section.

Summary of sections: 15AFSC, 1/1.

16) SOURCE: Right Tongue Base and Pharyngeal Wall

[page 6 of 8]
Received fresh labeled "right tongue base and pharyngeal wall, stitch anterior, small piece is posterior to main specimen" is a 22.0 gram portion of tongue that measures 5.0 cm anteriorly to posteriorly, 5.0 cm transversely, and 1.8 cm superiorly to inferiorly. The superior surface of the tongue is pink-tan with multiple small nodules consistent with normal tongue mucosa. The specimen is oriented with a stitch at the anterior margin. The specimen is inked as follows: anterior-yellow, posterior-black, deep-red. Abutting the tongue surface is pink-tan smooth mucosa. There is a central circular incision with tissue removed on the superior surface. This area measures 2.4 x 2.3 cm and is 1.0 cm deep into the specimen. The specimen is serially sectioned perpendicular to the anterior margin to reveal a firm white lesion extending from the mucosal surface to the muscle. The lesion measures 2.5 x 2.5 x 1.3 cm. It is less than 0.1 cm from the deep margin, 0.1 cm from the closest anterior margin, and 1.0 cm from the closest posterior margin. Also received separate from the main specimen is a 1.8 x 1.2 x 0.7 cm portion of pink-tan soft tissue with a focal mucosal lining. This specimen is inked entirely black. It is serially sectioned to reveal a small focus of firm white tissue similar to the previous tissue that measures 1.1 cm in greatest extent. A portion of tissue is given to research, placed in glutaraldehyde, and frozen at -80 degrees. Representative sections of the main specimen and separately received small mass are submitted.

Summary of sections: 16AFSC, mass to closest anterior margin, 1/1; 16B, mass to closest posterior margin, 1/1; 16C, mass to closest deep margin, 1/1; 16D-16E, representative sections of mass, 2/1 each; 16F, representative sections of normal tongue, 2/1; 16G, representative sections of small separately received nodule, 2/1.

17) SOURCE: Anterior Tongue Base Mucosal Margin

Received fresh on a towel and labeled "anterior tongue base mucosal margin" is a 4.8 x 0.6 x 0.1 cm portion of pink-tan mucosa with a portion of tongue surface on one end. The specimen is oriented with the letter "R" written on the towel and the right side of the specimen is inked black. The specimen is submitted entirely for frozen section.

Summary of sections: 17AFSC, 1/1.

18) SOURCE: Anterior Oral Tongue Margin

Received fresh on a towel labeled "anterior oral tongue margin" is a 2.5 x 0.7 x 0.6 cm strip of pink-tan soft tissue with one edge of tongue surface. The specimen is oriented with the letter "R" written on the towel and the right side of the specimen is inked black. The specimen is submitted entirely for frozen section.

Summary of sections: 18AFSC, 1/1.

19) SOURCE: Right Pharyngeal Wall Mucosal Margin #2

Received fresh on a towel labeled "right pharyngeal wall mucosal margin #2" is a 4.0 x 0.2 x 0.1 cm strip of pink-tan soft tissue. The specimen is oriented with the letter "S" on the towel and the superior edge of the specimen is inked black. The specimen is submitted entirely for frozen section.

Summary of sections: 19AFSC, 1/1.

[page 7 of 8]
[REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Anterior Inferior Left Neck Skin Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

2) SOURCE: Anterior Superior Left Neck Skin Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED] [REDACTED]

3) SOURCE: Posterior Left Neck Skin Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED] [REDACTED]

10) SOURCE: Right Tongue Base Biopsy

FROZEN SECTION DIAGNOSIS: INVOLVED BY CARCINOMA. [REDACTED] [REDACTED]

11) SOURCE: Stomal Mucosa Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED] [REDACTED]

12) SOURCE: Post Cricoid Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED] [REDACTED]

13) SOURCE: Right Pharyngeal Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED] [REDACTED]

14) SOURCE: Left Pharyngeal Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED] [REDACTED]

15) SOURCE: Tongue Base Mucosal Margin

FROZEN SECTION DIAGNOSIS: AT LEAST SQUAMOUS CELL CARCINOMA IN SITU. [REDACTED] [REDACTED]

17) SOURCE: Anterior Tongue Base Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED] [REDACTED]

18) SOURCE: Anterior Oral Tongue Margin

[REDACTED]

[page 8 of 8]
FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

19) SOURCE: Right Pharyngeal Wall Mucosal Margin #2

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

Electronically signed by: [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file cf94516c-81e2-4842-b9da-9717c7986440 (TCGA-CR-6474.36A37135-DE10-4F1E-A021-C73E23E6021F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).